Somatic mutation profile of tumor specimen ALCH-B2CQ-TTP1-A (aliquot ALCH-B2CQ-TTP1-A-1-0-D-A776-36) from ALCHEMIST case ALCH-B2CQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.9 years (25,911 days).
Specimen ALCH-B2CQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcf05bb2-a8c5-4fbb-affb-f1818365cf4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2CQ-NB1-A (Blood Derived Normal), aliquot ALCH-B2CQ-NB1-A-1-0-D-A776-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/696b8f97-ae20-4fe9-bd5a-3ac1a73a9422

The open-access MAF lists 84 somatic variants for this specimen: 58 protein-altering or splice-affecting, 16 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 16, Intron 4, Nonsense Mutation 4, RNA 3, 5'UTR 2, Frame Shift Ins 2, 5'Flank 1, Frame Shift Del 1, Splice Site 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 52/362 reads (14%) | hotspot (GDC flag); catalogued as rs377767360, CM000742, COSV61685033; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AKAP12 | c.3655G>C p.E1219Q | Missense Mutation (SNP) | VAF 85/175 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as COSV53581280; called by muse, mutect2, varscan2
- ALK | c.1625C>G p.P542R | Missense Mutation (SNP) | VAF 129/635 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV66571802, COSV66588105; called by muse, mutect2, varscan2
- ARAF | c.665G>A p.S222N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.835); catalogued as rs775214073; called by mutect2, varscan2
- ATP6V1B1 | c.1124G>C p.R375T | Missense Mutation (SNP) | VAF 58/684 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV99314524; called by muse, mutect2
- CSF1R | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99642461; called by muse, mutect2
- ELOA2 | c.1824C>G p.Y608* | Nonsense Mutation (SNP) | VAF 73/245 reads (30%) | catalogued as rs267605191; called by muse, mutect2, varscan2
- EYA4 | c.1857+2T>C p.X619_splice (on ENST00000531901 / NM_001301013.1; = p.X613_splice on NM_004100.5) | Splice Site (SNP) | VAF 153/507 reads (30%) | catalogued as COSV62047096; called by muse, mutect2, varscan2
- FIGNL2 | c.1221G>C p.E407D | Missense Mutation (SNP) | VAF 68/214 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs756316690; called by muse, mutect2, varscan2
- FMO1 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100707990; called by muse, mutect2, varscan2
- GLI2 | c.2594C>A p.T865K (on ENST00000361492 / NM_001374353.1; = p.T882K on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100084652; called by muse, mutect2, varscan2
- GPR26 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 31/453 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.883); catalogued as rs1196848316, COSV52934458; called by muse, mutect2
- INTS4 | c.2600A>G p.Y867C | Missense Mutation (SNP) | VAF 68/256 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs549287015; called by muse, mutect2, varscan2
- KPTN | c.711G>A p.E237= | Splice Region (SNP) | VAF 43/233 reads (18%) | catalogued as rs759159595; called by muse, mutect2, varscan2
- LIG3 | c.469dup p.I157Nfs*16 | Frame Shift Ins (INS) | VAF 88/299 reads (29%) | catalogued as rs745989900; called by mutect2, varscan2
- LORICRIN | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 17/52 reads (33%) | PolyPhen benign (0.081); catalogued as rs777340389; called by muse, mutect2, varscan2
- MYBPC1 | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 289/699 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.197); catalogued as COSV62254428; called by muse, mutect2, varscan2
- NRXN3 | c.2629A>T p.T877S (on ENST00000335750 / NM_001330195.2; = p.T504S on NM_004796.6) | Missense Mutation (SNP) | VAF 215/407 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.225); catalogued as rs775022761; called by muse, mutect2, varscan2
- OR2T33 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 88/413 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.559); catalogued as rs374091097; called by muse, varscan2
- OR2T8 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.559); catalogued as COSV60665026; called by mutect2, varscan2
- PCDHGB4 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as COSV53910723; called by muse, mutect2, varscan2
- POLM | c.1247G>C p.R416T | Missense Mutation (SNP) | VAF 78/220 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99641676; called by muse, mutect2, varscan2
- RTN1 | c.1268C>T p.A423V | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs1014346787, COSV50718522; called by muse, mutect2
- SEC16B | c.2167C>G p.R723G | Missense Mutation (SNP) | VAF 134/286 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as rs767106935; called by muse, mutect2, varscan2
- ANKAR | c.3589G>A p.V1197I | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD61 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- BCAN | c.2315G>T p.G772V | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CLCA2 | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNTNAP2 | c.191A>T p.K64M | Missense Mutation (SNP) | VAF 40/862 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- DEGS1 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- DENND4B | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 50/272 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- DIS3 | c.2438_2440del p.I813_C814delinsS | In Frame Del (DEL) | VAF 98/213 reads (46%) | called by mutect2, pindel, varscan2
- EDRF1 | c.1597G>T p.E533* (on ENST00000356792 / NM_001202438.2; = p.E499* on NM_015608.2) | Nonsense Mutation (SNP) | VAF 92/475 reads (19%) | called by muse, mutect2, varscan2
- F2RL2 | c.951C>A p.S317R | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- GLRX3 | c.505C>T p.L169F | Missense Mutation (SNP) | VAF 78/233 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- HSPA1L | c.1195G>C p.A399P | Missense Mutation (SNP) | VAF 114/402 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- HYDIN | c.4976G>T p.R1659I | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- HYLS1 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 39/472 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.17); called by muse, mutect2
- KIF1B | c.4190C>G p.P1397R (on ENST00000377086 / NM_001365952.1; = p.P1351R on NM_015074.3) | Missense Mutation (SNP) | VAF 38/750 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- METTL16 | c.320T>C p.I107T | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NBN | c.2126T>C p.I709T | Missense Mutation (SNP) | VAF 246/712 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- NUTM2E | c.2535G>T p.E845D | Missense Mutation (SNP) | VAF 62/740 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.221); called by muse, mutect2
- PDE8B | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 135/426 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- PRB2 | c.119C>A p.P40H | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT tolerated, low confidence (0.39); PolyPhen possibly damaging (0.551); called by muse, mutect2
- PTPN13 | c.1816G>A p.G606S | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SESN3 | c.833A>C p.D278A | Missense Mutation (SNP) | VAF 41/435 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.396); called by muse, mutect2
- SLC35G4 | c.212A>G p.E71G | Missense Mutation (SNP) | VAF 110/256 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SREBF1 | c.1181G>C p.S394T | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.304); called by muse, mutect2
- SS18L1 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 72/232 reads (31%) | called by muse, mutect2, varscan2
- STK33 | c.1334A>G p.E445G | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SYT13 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 77/559 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TLL1 | c.3007A>C p.I1003L | Missense Mutation (SNP) | VAF 26/528 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- TSPY2 | c.608T>G p.L203W | Missense Mutation (SNP) | VAF 36/1622 reads (2%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2
- UCHL1 | c.71G>C p.G24A | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2
- UQCRC1 | c.766_785del p.T256Afs*12 | Frame Shift Del (DEL) | VAF 39/269 reads (14%) | called by mutect2, pindel, varscan2
- USP31 | c.773C>A p.P258Q | Missense Mutation (SNP) | VAF 80/226 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- YLPM1 | c.1064dup p.P356Sfs*3 | Frame Shift Ins (INS) | VAF 44/327 reads (13%) | called by mutect2, pindel, varscan2
- ZNF597 | c.575T>A p.I192N | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ALPK2 | c.4719T>C p.V1573= | Silent (SNP) | VAF 130/248 reads (52%) | called by muse, mutect2, varscan2
- CARD11 | c.2247G>T p.L749= | Silent (SNP) | VAF 32/208 reads (15%) | called by muse, mutect2, varscan2
- CHIA | c.633C>T p.T211= (on ENST00000343320; = p.T103= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 64/261 reads (25%) | catalogued as rs781153179, COSV58473693; called by muse, mutect2, varscan2
- IL6R | c.444C>G p.L148= | Silent (SNP) | VAF 138/860 reads (16%) | catalogued as rs1352622176; called by muse, varscan2
- KIF21A | c.4329A>C p.R1443= (on ENST00000361418 / NM_001378440.1; = p.R1430= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 219/510 reads (43%) | called by muse, mutect2, varscan2
- MED23 | c.3678C>G p.L1226= | Silent (SNP) | VAF 17/301 reads (6%) | catalogued as rs755765025; called by muse, mutect2
- MYH1 | c.171G>T p.G57= | Silent (SNP) | VAF 157/501 reads (31%) | called by muse, mutect2, varscan2
- NDUFC1 | c.27C>T p.P9= | Silent (SNP) | VAF 56/190 reads (29%) | catalogued as rs140979926; called by muse, mutect2, varscan2
- NOBOX | c.660G>A p.P220= | Silent (SNP) | VAF 14/265 reads (5%) | catalogued as rs1457254748, COSV56198292; called by muse, mutect2
- PCDHB6 | c.2205G>T p.V735= | Silent (SNP) | VAF 107/357 reads (30%) | called by muse, mutect2, varscan2
- SCAPER | c.2541C>T p.D847= | Silent (SNP) | VAF 36/494 reads (7%) | called by muse, mutect2
- SLC10A2 | c.468G>A p.G156= | Silent (SNP) | VAF 35/341 reads (10%) | catalogued as rs748275897; called by muse, mutect2, varscan2
- SORCS3 | c.1968C>T p.D656= | Silent (SNP) | VAF 79/281 reads (28%) | catalogued as rs372850065; called by muse, mutect2, varscan2
- SP9 | c.1389G>A p.A463= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs898034776, COSV67602107; called by muse, mutect2, varscan2
- UBR5 | c.1062A>G p.V354= | Silent (SNP) | VAF 24/456 reads (5%) | called by muse, mutect2
- USH2A | c.3675C>T p.S1225= | Silent (SNP) | VAF 74/262 reads (28%) | catalogued as rs763565842, COSV100232837, COSV56381241; called by muse, mutect2, varscan2
- ASH1L | chr1:155563256 G>C | 5'Flank (SNP) | VAF 34/208 reads (16%) | called by muse, mutect2, varscan2
- CCDC186 | c.-118del | 5'UTR (DEL) | VAF 63/348 reads (18%) | called by mutect2, pindel, varscan2
- DNAI2 | c.1211+1805G>T | Intron (SNP) | VAF 15/239 reads (6%) | called by muse, mutect2
- GRM2 | c.1288+650C>T | Intron (SNP) | VAF 12/83 reads (14%) | catalogued as rs1001750717; called by muse, mutect2, varscan2
- HSPB1 | c.-13A>G | 5'UTR (SNP) | VAF 93/371 reads (25%) | called by muse, mutect2, varscan2
- OFCC1 | n.471C>T | RNA (SNP) | VAF 20/500 reads (4%) | called by muse, mutect2
- OFCC1 | n.114G>A | RNA (SNP) | VAF 92/314 reads (29%) | called by muse, mutect2, varscan2
- RFPL4AP1 | n.806A>T | RNA (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- TPK1 | c.185+1097G>A | Intron (SNP) | VAF 22/604 reads (4%) | catalogued as rs773059578; called by muse, mutect2
- ZNF211 | c.90+422A>C | Intron (SNP) | VAF 55/172 reads (32%) | called by muse, mutect2, varscan2
